Somatic mutation profile of tumor specimen TCGA-AB-2807-03B (aliquot TCGA-AB-2807-03B-01W-0728-08) from TCGA case TCGA-AB-2807, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.8 years (25,143 days).
Specimen TCGA-AB-2807-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19aff4c3-70c6-41d4-9db8-ac7dc526b1e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2807-11B (Solid Tissue Normal), aliquot TCGA-AB-2807-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8742ad7e-0347-421a-b575-7979a7b4a99c

The open-access MAF lists 221 somatic variants for this specimen: 158 protein-altering or splice-affecting, 59 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 138, Silent 59, Nonsense Mutation 11, Frame Shift Ins 4, Splice Site 3, Intron 2, 5'UTR 1, 5'Flank 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5423C>T p.A1808V | Missense Mutation (SNP) | VAF 42/1302 reads (3%) | SIFT tolerated (1); PolyPhen possibly damaging (0.869); catalogued as rs1004237594, COSV100933075; called by muse, mutect2
- ABCB9 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV54894657; called by muse, mutect2
- ABCC12 | c.860T>C p.F287S | Missense Mutation (SNP) | VAF 35/425 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.542); catalogued as COSV100252379; called by muse, mutect2
- ADGRA2 | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55105921; called by muse, varscan2
- AKAP12 | c.4216G>A p.V1406I | Missense Mutation (SNP) | VAF 278/773 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53583604; called by muse, mutect2, varscan2
- ALG9 | c.743G>T p.W248L | Missense Mutation (SNP) | VAF 21/695 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs1429052183; called by muse, mutect2
- ANKFN1 | c.1715G>A p.S572N | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as COSV100593304; called by muse, mutect2
- ANKRD11 | c.7754G>A p.R2585H | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567537296, COSV56357603; called by muse, mutect2
- APOBEC3G | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 20/515 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.816); catalogued as COSV101349060; called by muse, mutect2
- ARMC1 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99394877; called by muse, mutect2
- ARSH | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 35/977 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101139783, COSV66964036; called by muse, mutect2
- ATP2B3 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.316); catalogued as COSV54859151; called by muse, mutect2
- BACH1 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 36/1426 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99728060; called by muse, mutect2
- BCORL1 | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.242); catalogued as COSV99498941; called by muse, mutect2
- BCORL1 | c.3343C>T p.P1115S | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); catalogued as COSV99498945; called by muse, mutect2
- BDKRB1 | c.389C>G p.A130G | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53706935, COSV99387789; called by muse, mutect2
- BRSK1 | c.1049T>C p.I350T | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100473833; called by muse, mutect2
- C15orf40 | c.318T>A p.Y106* | Nonsense Mutation (SNP) | VAF 17/274 reads (6%) | catalogued as COSV100417302; called by muse, mutect2
- CAD | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99254723; called by muse, mutect2
- CARD6 | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV99620528; called by muse, mutect2
- CASP14 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 39/1158 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99692980, COSV99693083; called by muse, mutect2
- CATSPER1 | c.1709A>G p.Q570R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV56414022; called by mutect2, varscan2
- CCDC146 | c.2722C>T p.Q908* | Nonsense Mutation (SNP) | VAF 20/665 reads (3%) | catalogued as COSV99592371; called by muse, mutect2
- CHD3 | c.3397C>A p.L1133I | Missense Mutation (SNP) | VAF 71/823 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57875382; called by muse, mutect2
- CIT | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 32/1078 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV55877111; called by muse, mutect2
- CNTNAP5 | c.143A>T p.D48V | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.864); catalogued as COSV70515839; called by muse, mutect2
- COG5 | c.1625G>A p.G542E | Missense Mutation (SNP) | VAF 35/926 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as COSV99771716; called by muse, mutect2
- COL27A1 | c.1028G>A p.G343D | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV100620859; called by muse, mutect2
- CPAMD8 | c.3455T>C p.L1152P (on ENST00000651564; = p.L1105P on NM_015692.5) | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71597502; called by muse, mutect2, varscan2
- CRYZL1 | c.490T>A p.L164I | Missense Mutation (SNP) | VAF 14/440 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99280885; called by muse, mutect2
- CSNK1G1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 181/732 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as rs774148858, COSV57378402; called by muse, mutect2, varscan2
- DAXX | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 24/832 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs200273259, COSV56470299; called by muse, mutect2
- DNAJC10 | c.1589A>T p.N530I | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1428855986, COSV51148846; called by muse, mutect2
- DOCK3 | c.4523A>G p.E1508G | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99810393; called by muse, mutect2
- EDC4 | c.1949C>G p.P650R | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.099); catalogued as rs1311082849, COSV100197562; called by muse, mutect2
- ERBB4 | c.1199-2A>G p.X400_splice | Splice Site (SNP) | VAF 18/208 reads (9%) | catalogued as COSV99619596; called by muse, mutect2
- FAM13A | c.1521G>C p.W507C | Missense Mutation (SNP) | VAF 16/488 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.123); catalogued as COSV99983183; called by muse, mutect2
- FAM83D | c.617G>A p.C206Y | Missense Mutation (SNP) | VAF 45/1302 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167683599, COSV99465115; called by muse, mutect2
- FAT4 | c.10402G>A p.A3468T | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.275); catalogued as COSV100627911; called by muse, mutect2
- FBXL19 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 82/461 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV57946034; called by muse, mutect2, varscan2
- FGF10 | c.430A>T p.K144* | Nonsense Mutation (SNP) | VAF 13/351 reads (4%) | catalogued as COSV52934619; called by muse, mutect2
- FGF8 | c.380G>A p.C127Y (on ENST00000344255 / NM_033164.4; = p.C109Y on NM_006119.6) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60143853; called by muse, mutect2
- FKBP10 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58635265; called by muse, mutect2
- GCN1 | c.7270C>T p.R2424W | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56102972; called by muse, mutect2, varscan2
- GK2 | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 62/682 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62628655; called by muse, mutect2
- GMPR2 | c.536G>A p.G179E (on ENST00000355299 / NM_001351022.2; = p.G197E on NM_016576.5) | Missense Mutation (SNP) | VAF 44/524 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754067969, COSV51662121; called by muse, mutect2
- GPHN | c.1298T>C p.I433T (on ENST00000315266 / NM_001377519.1; = p.I466T on NM_020806.5) | Missense Mutation (SNP) | VAF 30/1017 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV100015781; called by muse, mutect2
- GPS2 | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV100222824, COSV59748282; called by muse, mutect2
- GRIN2B | c.3898C>T p.R1300W | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565453201, COSV74206505; called by muse, mutect2
- H2BC14 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 17/444 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.193); catalogued as COSV100297534; called by muse, mutect2
- HDAC6 | c.3098dup p.T1034Nfs*55 | Frame Shift Ins (INS) | VAF 14/91 reads (15%) | catalogued as rs781824028; called by mutect2, varscan2
- HIVEP1 | c.7522C>T p.P2508S | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV101044993; called by muse, mutect2
- HNRNPUL1 | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 17/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647075; called by muse, mutect2
- ICAM3 | c.83A>T p.Q28L | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV99348955; called by muse, mutect2
- IFT140 | c.903A>T p.R301S | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV68504059; called by muse, mutect2, varscan2
- IMPG2 | c.868A>T p.I290F | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51983210; called by muse, mutect2
- IQCN | c.2351C>T p.A784V | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV66578783; called by muse, mutect2, varscan2
- IRF2 | c.783G>C p.Q261H | Missense Mutation (SNP) | VAF 127/1389 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.187); catalogued as COSV66930890; called by muse, mutect2
- JADE2 | c.89G>T p.C30F | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.593); catalogued as COSV99252982; called by muse, mutect2
- KATNA1 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 25/410 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100167725; called by muse, mutect2
- KBTBD4 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.598); catalogued as COSV100442843; called by muse, mutect2
- KIAA1614 | c.3113G>T p.G1038V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV62551972; called by muse, mutect2, varscan2
- KRBA2 | c.638T>A p.L213H | Missense Mutation (SNP) | VAF 22/726 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.283); catalogued as COSV100497628; called by muse, mutect2
- KRT20 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764730297, COSV51426070; called by muse, mutect2, varscan2
- KRT23 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99266158; called by muse, mutect2
- KRT77 | c.441G>C p.E147D | Missense Mutation (SNP) | VAF 24/1030 reads (2%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV100526990; called by muse, mutect2
- KRT85 | c.881A>G p.E294G | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV99225264; called by muse, mutect2
- LILRA6 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 20/467 reads (4%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.712); catalogued as rs1474959562; called by muse, mutect2
- LMO7 | c.3148G>A p.G1050R (on ENST00000357063; = p.G731R on NM_005358.5) | Missense Mutation (SNP) | VAF 20/542 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.309); catalogued as COSV100412662, COSV100412787; called by muse, mutect2
- LPA | c.5307C>A p.Y1769* | Nonsense Mutation (SNP) | VAF 18/500 reads (4%) | catalogued as COSV100306451, COSV60296327; called by muse, mutect2
- LPL | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 23/718 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100255733; called by muse, mutect2
- MAGEC2 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 56/868 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.11); catalogued as COSV99909481; called by muse, mutect2
- MAGT1 | c.402T>A p.N134K (on ENST00000618282 / NM_001367916.1; = p.N166K on NM_032121.5) | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100800139; called by muse, mutect2
- METTL14 | c.1189C>G p.P397A | Missense Mutation (SNP) | VAF 10/221 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101183382; called by muse, mutect2
- MPHOSPH9 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 70/1314 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs773625797, COSV56616819; called by muse, mutect2
- MRPS5 | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 16/510 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99720753; called by muse, mutect2
- MSH5 | c.2201A>T p.D734V | Missense Mutation (SNP) | VAF 28/1162 reads (2%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100991782; called by muse, mutect2
- MYH11 | c.4073C>T p.A1358V | Missense Mutation (SNP) | VAF 49/773 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV100258257; called by muse, mutect2
- MYH3 | c.3310C>T p.Q1104* | Nonsense Mutation (SNP) | VAF 8/125 reads (6%) | catalogued as COSV99877964; called by muse, mutect2
- MYRIP | c.1063T>C p.W355R | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100218704; called by muse, mutect2
- NID1 | c.3619C>T p.Q1207* | Nonsense Mutation (SNP) | VAF 20/292 reads (7%) | catalogued as COSV99937255; called by muse, mutect2
- NIT2 | c.466A>G p.M156V | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1464918436, COSV101237085; called by muse, mutect2
- NMUR2 | c.536T>A p.L179Q | Missense Mutation (SNP) | VAF 13/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99676749; called by muse, mutect2
- NODAL | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 65/570 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54662829; called by muse, mutect2, varscan2
- NPR1 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 15/486 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV100902000; called by muse, mutect2
- NUAK2 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1273001242, COSV100904008; called by muse, mutect2
- NUP210 | c.3569C>T p.T1190I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as COSV99595878; called by muse, mutect2
- OR7A17 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 46/1020 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100541590; called by muse, mutect2
- PARP12 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 23/592 reads (4%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99693933; called by muse, mutect2
- PCLO | c.13313G>A p.R4438H | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs773610201, COSV61618185; called by muse, mutect2, varscan2
- PHF12 | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 16/292 reads (5%) | catalogued as COSV99255621; called by muse, mutect2
- PHKA2 | c.3409C>T p.R1137W | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101176871; called by muse, mutect2
- PLAGL1 | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV99394244; called by muse, mutect2
- PLXNA4 | c.2549G>A p.G850D | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.062); catalogued as COSV100323882, COSV100325926, COSV58164562; called by muse, mutect2
- POLR2E | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 39/70 reads (56%) | catalogued as COSV53125521; called by muse, mutect2, varscan2
- POM121L12 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.573); catalogued as rs565383229, COSV68693234; called by muse, mutect2, varscan2
- PPIC | c.581T>C p.I194T | Missense Mutation (SNP) | VAF 64/1254 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100120561; called by muse, mutect2
- PRR19 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1162575423, COSV100003719; called by muse, mutect2
- PTPN13 | c.334dup p.A112Gfs*2 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | catalogued as rs762510393; called by pindel, varscan2
- RAB24 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 76/405 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as COSV57464286; called by muse, mutect2, varscan2
- RAB28 | c.217A>T p.T73S | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99986131; called by muse, mutect2
- REPIN1 | c.1598A>T p.H533L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101262600; called by muse, mutect2
- RIPOR1 | c.688-2A>G p.X230_splice (on ENST00000379312 / NM_001193522.2; = p.X226_splice on NM_024519.4) | Splice Site (SNP) | VAF 28/443 reads (6%) | catalogued as COSV99242782; called by muse, mutect2
- RNF5 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV61248860; called by muse, mutect2, varscan2
- RNMT | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51084276, COSV51091802; called by muse, mutect2
- SAXO2 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.087); catalogued as rs933256705, COSV59755623; called by muse, mutect2, varscan2
- SEPTIN4 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 17/414 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.692); catalogued as COSV100400273; called by muse, mutect2
- SHKBP1 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 14/422 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52538814; called by muse, mutect2
- SIGLEC1 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV52474640; called by muse, mutect2, varscan2
- SLC23A2 | c.1165G>C p.A389P | Missense Mutation (SNP) | VAF 70/888 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100594923; called by muse, mutect2
- SLC35F3 | c.752T>A p.L251* (on ENST00000366617 / NM_001300845.1; = p.L320* on NM_173508.4) | Nonsense Mutation (SNP) | VAF 26/742 reads (4%) | catalogued as COSV64019543; called by muse, mutect2
- SLC5A2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 23/675 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1301506630, COSV100393096; called by muse, mutect2
- SMC1A | c.3391G>A p.G1131R | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447632, COSV59130934; called by muse, mutect2
- SNX33 | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 14/177 reads (8%) | catalogued as COSV100145755; called by muse, mutect2
- SP100 | c.2255A>G p.E752G | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100413705; called by muse, mutect2
- SPTB | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 22/161 reads (14%) | catalogued as COSV67635658; called by muse, mutect2, varscan2
- SRA1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 127/1040 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV51860386; called by mutect2, varscan2
- STK10 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV99451208; called by muse, mutect2
- SYNE1 | c.7200G>T p.Q2400H (on ENST00000367255 / NM_182961.4; = p.Q2407H on NM_033071.3) | Missense Mutation (SNP) | VAF 28/1112 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as COSV54973356; called by muse, mutect2
- TANC1 | c.3946T>A p.L1316I | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55098824; called by muse, mutect2, varscan2
- TAS1R1 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100062874; called by muse, mutect2
- TAS2R7 | c.159A>G p.I53M | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); catalogued as COSV53691448; called by muse, mutect2
- TBC1D10B | c.1833G>C p.E611D | Missense Mutation (SNP) | VAF 15/345 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs1229481788, COSV99977013; called by muse, mutect2
- TBC1D8 | c.2456A>C p.E819A | Missense Mutation (SNP) | VAF 132/272 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV65217364; called by muse, mutect2, varscan2
- TENM3 | c.3467G>A p.R1156H | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1393753481, COSV69320762; called by muse, mutect2, varscan2
- TMPRSS4 | c.647G>C p.W216S | Missense Mutation (SNP) | VAF 21/592 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101449364; called by muse, mutect2
- TNRC6C | c.4580G>T p.G1527V | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV100049689; called by muse, mutect2
- TRPM1 | c.2222T>C p.L741P | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs774535578, COSV99855653; called by muse, mutect2
- TRPV3 | c.1007C>G p.T336S | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100027590; called by muse, mutect2
- TTPA | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 52/736 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV52647242; called by muse, mutect2
- TUB | c.700G>C p.A234P (on ENST00000299506 / NM_177972.3; = p.A289P on NM_003320.4) | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.638); catalogued as COSV100210112; called by muse, mutect2
- TUBA3C | c.821C>A p.P274Q | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV67139426; called by muse, mutect2
- TWNK | c.940T>C p.S314P | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV99272178; called by muse, mutect2
- TYRO3 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV55481030; called by muse, mutect2
- UBA1 | c.2275-1G>C p.X759_splice | Splice Site (SNP) | VAF 20/720 reads (3%) | catalogued as COSV100255556; called by muse, mutect2
- UBA1 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 33/638 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as COSV100255559; called by muse, mutect2
- USH2A | c.12186A>T p.L4062F | Missense Mutation (SNP) | VAF 68/1001 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV100232002; called by muse, mutect2
- USP6 | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 104/183 reads (57%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.268); catalogued as COSV51499300; called by muse, mutect2, varscan2
- UVRAG | c.1307T>A p.L436Q | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100638270, COSV62102967; called by muse, mutect2
- ZBTB7C | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.261); catalogued as COSV100134332; called by muse, mutect2
- ZDHHC23 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1449084217; called by muse, mutect2
- ZNF354A | c.1343G>T p.S448I | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100234406; called by muse, mutect2
- ZNF530 | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 29/917 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as COSV100252463; called by muse, mutect2
- ZNF74 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV62624932; called by muse, mutect2, varscan2
- ASXL1 | c.2213del p.G738Dfs*6 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- CASC3 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 7/204 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2
- CWC25 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 24/621 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- DONSON | c.518G>C p.W173S | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ESYT3 | c.761G>A p.G254D | Missense Mutation (SNP) | VAF 36/542 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ETV2 | c.939dup p.R314Afs*? | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- GFRA2 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV4-69 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- ITSN2 | c.3635G>A p.G1212D | Missense Mutation (SNP) | VAF 28/1054 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.151); called by muse, mutect2
- NPAS1 | c.1369dup p.Q457Pfs*155 | Frame Shift Ins (INS) | VAF 12/120 reads (10%) | called by mutect2, pindel
- RUNX1 | c.420_425del p.S140_G141del (on ENST00000344691 / NM_001001890.3; = p.S167_G168del on NM_001754.5) | In Frame Del (DEL) | VAF 139/300 reads (46%) | called by mutect2, pindel, varscan2
- SLC29A1 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 14/478 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSC22D2 | c.1625G>C p.S542T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- VCAN | c.1007C>A p.P336H | Missense Mutation (SNP) | VAF 104/3554 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.153); called by muse, mutect2
- ADGRE5 | c.1686G>A p.L562= (on ENST00000242786 / NM_078481.4; = p.L469= on NM_001784.5) | Silent (SNP) | VAF 24/189 reads (13%) | catalogued as COSV54393624; called by muse, mutect2, varscan2
- BCL7A | c.228C>G p.T76= | Silent (SNP) | VAF 14/287 reads (5%) | catalogued as COSV99946872; called by muse, mutect2
- CACNA1E | c.3528C>A p.V1176= | Silent (SNP) | VAF 39/650 reads (6%) | catalogued as COSV100701659, COSV62381312; called by muse, mutect2
- CAMP | c.126G>T p.V42= (on ENST00000296435; = p.V39= on NM_004345.5) | Silent (SNP) | VAF 269/665 reads (40%) | catalogued as rs756903752, COSV56482385; called by muse, mutect2, varscan2
- CARS1 | c.1110G>A p.R370= | Silent (SNP) | VAF 16/488 reads (3%) | catalogued as COSV99542338; called by muse, mutect2
- CD48 | c.612C>T p.S204= | Silent (SNP) | VAF 22/624 reads (4%) | catalogued as rs1200744694, COSV100924204; called by muse, mutect2
- CTTNBP2NL | c.363G>A p.R121= | Silent (SNP) | VAF 324/824 reads (39%) | catalogued as COSV54747572; called by mutect2, varscan2
- DMKN | c.660G>A p.V220= | Silent (SNP) | VAF 25/311 reads (8%) | catalogued as rs1464107259, COSV100303371; called by muse, mutect2
- ECEL1 | c.996G>A p.R332= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as rs774508401, COSV58812078; called by muse, mutect2, varscan2
- EFTUD2 | c.1635T>C p.P545= | Silent (SNP) | VAF 20/536 reads (4%) | catalogued as COSV101274526; called by muse, mutect2
- EXT2 | c.768A>G p.S256= (on ENST00000343631; = p.S289= on NM_000401.3) | Silent (SNP) | VAF 10/205 reads (5%) | catalogued as rs1565203614, COSV100640549; called by muse, mutect2
- HERC1 | c.13515C>T p.L4505= | Silent (SNP) | VAF 15/551 reads (3%) | called by muse, mutect2
- HTR6 | c.273C>T p.R91= | Silent (SNP) | VAF 11/123 reads (9%) | catalogued as COSV57034929; called by muse, mutect2
- INPP5F | c.3258A>G p.Q1086= | Silent (SNP) | VAF 10/216 reads (5%) | catalogued as COSV100740053; called by muse, mutect2
- ITM2A | c.291T>C p.P97= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV100964431; called by muse, mutect2
- KCNN3 | c.2088G>A p.L696= (on ENST00000618040 / NM_001204087.1; = p.L681= on NM_002249.6) | Silent (SNP) | VAF 12/330 reads (4%) | catalogued as COSV99677895; called by muse, mutect2
- KDM5C | c.3399G>A p.L1133= | Silent (SNP) | VAF 20/614 reads (3%) | catalogued as COSV100948961; called by muse, mutect2
- KLK1 | c.624C>T p.D208= | Silent (SNP) | VAF 8/173 reads (5%) | called by muse, mutect2
- KRT5 | c.1314C>A p.A438= | Silent (SNP) | VAF 228/530 reads (43%) | catalogued as COSV52863948, COSV99357963; called by muse, varscan2
- KRTAP10-12 | c.93C>T p.D31= | Silent (SNP) | VAF 53/1008 reads (5%) | catalogued as COSV100552538; called by muse, mutect2
- KRTAP10-7 | c.894C>T p.C298= | Silent (SNP) | VAF 24/592 reads (4%) | catalogued as COSV100170085; called by muse, mutect2
- MAGEA1 | c.504C>A p.S168= | Silent (SNP) | VAF 14/274 reads (5%) | catalogued as COSV63119354; called by muse, mutect2
- MTMR14 | c.249C>T p.G83= | Silent (SNP) | VAF 14/448 reads (3%) | catalogued as COSV56006431; called by muse, mutect2
- MXRA5 | c.6696G>A p.V2232= | Silent (SNP) | VAF 10/279 reads (4%) | catalogued as COSV54245354; called by muse, mutect2
- MYL3 | c.417C>G p.V139= | Silent (SNP) | VAF 40/1006 reads (4%) | catalogued as COSV99439405; called by muse, mutect2
- NAA25 | c.2850G>A p.L950= | Silent (SNP) | VAF 18/273 reads (7%) | catalogued as rs775034391, COSV99927452; called by muse, mutect2
- NCK2 | c.234C>A p.G78= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- NFKB2 | c.603T>C p.S201= | Silent (SNP) | VAF 26/542 reads (5%) | catalogued as COSV99192288; called by muse, mutect2
- NOBOX | c.861A>G p.L287= | Silent (SNP) | VAF 8/245 reads (3%) | called by muse, mutect2
- NUP153 | c.2409T>C p.C803= | Silent (SNP) | VAF 24/456 reads (5%) | catalogued as rs999275917, COSV100020052; called by muse, mutect2
- OR4A15 | c.544T>C p.L182= | Silent (SNP) | VAF 24/808 reads (3%) | catalogued as COSV100123941; called by muse, mutect2
- OVOL1 | c.264C>G p.G88= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100256779; called by muse, mutect2
- PAMR1 | c.207C>T p.C69= | Silent (SNP) | VAF 30/693 reads (4%) | catalogued as COSV53511226; called by muse, mutect2
- PDCD11 | c.339T>C p.T113= | Silent (SNP) | VAF 30/775 reads (4%) | catalogued as COSV100874277; called by muse, mutect2
- PLEKHG1 | c.3780A>G p.Q1260= | Silent (SNP) | VAF 17/147 reads (12%) | catalogued as rs768474388, COSV62051748; called by muse, mutect2, varscan2
- PLEKHG4 | c.3108G>A p.V1036= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as rs749794511, COSV100430780, COSV58575546; called by muse, mutect2
- PNMA5 | c.108G>A p.Q36= | Silent (SNP) | VAF 12/356 reads (3%) | called by muse, mutect2
- PPFIA3 | c.3516G>A p.L1172= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV99417701; called by muse, mutect2
- PPL | c.1800C>T p.L600= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100630629; called by muse, mutect2
- PPP1R12B | c.1428G>T p.R476= | Silent (SNP) | VAF 42/590 reads (7%) | catalogued as rs752223121, COSV100406846; called by muse, mutect2
- PRKCB | c.1059T>C p.F353= | Silent (SNP) | VAF 88/3302 reads (3%) | catalogued as COSV100333050; called by muse, mutect2
- PTX4 | c.222C>G p.V74= (on ENST00000447419 / NM_001328608.2; = p.V69= on NM_001013658.1) | Silent (SNP) | VAF 20/612 reads (3%) | catalogued as COSV99560308; called by muse, mutect2
- RNF123 | c.3294C>T p.D1098= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV100246505; called by muse, mutect2
- SALL4 | c.174G>A p.E58= | Silent (SNP) | VAF 12/337 reads (4%) | catalogued as COSV53855178; called by muse, mutect2
- SIDT2 | c.139C>T p.L47= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as COSV54058776; called by muse, mutect2
- SIPA1L3 | c.4929C>T p.D1643= | Silent (SNP) | VAF 11/171 reads (6%) | catalogued as COSV99727944; called by muse, mutect2
- SMG5 | c.2709G>T p.R903= | Silent (SNP) | VAF 11/157 reads (7%) | catalogued as COSV99430895; called by muse, mutect2
- SPON2 | c.825G>A p.P275= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1253058628, COSV52056728; called by muse, mutect2, varscan2
- TAS2R39 | c.993T>C p.L331= | Silent (SNP) | VAF 9/167 reads (5%) | catalogued as COSV101489402, COSV71470900; called by muse, mutect2
- TENT5C | c.348T>C p.L116= | Silent (SNP) | VAF 18/551 reads (3%) | catalogued as rs1362092246, COSV101032855; called by muse, mutect2
- TTLL4 | c.1944T>C p.P648= | Silent (SNP) | VAF 56/1570 reads (4%) | catalogued as COSV99293182; called by muse, mutect2
- TXNDC12 | c.258C>T p.S86= | Silent (SNP) | VAF 17/226 reads (8%) | catalogued as rs377040687; called by muse, mutect2
- UBN1 | c.1260C>T p.C420= | Silent (SNP) | VAF 14/317 reads (4%) | catalogued as COSV99277703; called by muse, mutect2
- UBN1 | c.3057C>T p.G1019= | Silent (SNP) | VAF 9/191 reads (5%) | catalogued as COSV99277704; called by muse, mutect2
- UCHL3 | c.369G>A p.L123= | Silent (SNP) | VAF 13/278 reads (5%) | catalogued as COSV101111523; called by muse, mutect2
- UCP1 | c.375A>G p.G125= | Silent (SNP) | VAF 25/516 reads (5%) | catalogued as COSV99530186; called by muse, mutect2
- WDR45B | c.909A>G p.T303= | Silent (SNP) | VAF 18/534 reads (3%) | catalogued as COSV101124428; called by muse, mutect2
- ZBTB49 | c.69G>C p.L23= | Silent (SNP) | VAF 34/1449 reads (2%) | catalogued as COSV100552418; called by muse, mutect2
- ZMAT1 | c.1557G>A p.K519= | Silent (SNP) | VAF 8/197 reads (4%) | called by muse, mutect2
- AGPAT4 | c.843+2325G>A | Intron (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1448-47C>A | Intron (SNP) | VAF 18/522 reads (3%) | called by muse, mutect2
- TSPOAP1 | chr17:58331264 T>C | 5'Flank (SNP) | VAF 110/206 reads (53%) | called by muse, mutect2, varscan2
- ZNF436 | c.-333G>C | 5'UTR (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
